Somatic mutation profile of tumor specimen MMRF_2194_2_BM_CD138pos (aliquot MMRF_2194_2_BM_CD138pos_T1_KHS5U_L14846) from MMRF case MMRF_2194, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.5 years (27,574 days).
Specimen MMRF_2194_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb694ddb-0c47-4d0c-b82a-5ab58f1e9af4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2194_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2194_1_PB_WBC_C3_KHS5U_L08801; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87c112a9-8056-4814-8059-ec5fed6185c1

The open-access MAF lists 233 somatic variants for this specimen: 94 protein-altering or splice-affecting, 30 silent, 109 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, 3'UTR 49, Silent 30, Intron 30, 5'UTR 14, Nonsense Mutation 9, RNA 7, 5'Flank 5, 3'Flank 4, Splice Site 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- ABCA12 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV55960224; called by muse, mutect2, varscan2
- ADAM12 | c.926T>A p.V309D | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64116378; called by muse, mutect2, varscan2
- AKAP11 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs541507380; called by muse, mutect2, varscan2
- CACNA1E | c.5810C>G p.S1937W | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1007685928, COSV62383196; called by muse, mutect2, varscan2
- CCKAR | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.356); catalogued as COSV55160045, COSV55164469; called by muse, mutect2, varscan2
- CCT7 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV99240927; called by muse, mutect2, varscan2
- CHD5 | c.4331A>C p.Q1444P | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1225701396; called by muse, mutect2
- DENND4C | c.4549C>G p.H1517D (on ENST00000434457 / NM_001330640.2; = p.H1468D on NM_017925.7) | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.586); catalogued as rs779176610; called by muse, mutect2, varscan2
- DNAJB9 | c.302G>T p.R101I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as rs1219797448; called by muse, mutect2, varscan2
- DOC2A | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 72/347 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV58752540; called by muse, mutect2, varscan2
- EEF1G | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 77/206 reads (37%) | catalogued as rs1418015966, COSV100240422; called by muse, mutect2, varscan2
- EIF4G3 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV51693788; called by muse, mutect2
- G6PC3 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1313517305; called by muse, mutect2, varscan2
- GABRA1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.257); catalogued as COSV50115453, COSV99196262; called by muse, mutect2, varscan2
- HDLBP | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 111/314 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV60500408; called by muse, mutect2, varscan2
- IGLV3-1 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs563308501; called by muse, mutect2, varscan2
- IKBKE | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV65626699; called by muse, mutect2
- IL4R | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs780006435, COSV50189985; called by muse, mutect2, varscan2
- KALRN | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53783272; called by muse, mutect2, varscan2
- LIMA1 | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as COSV57965146; called by muse, mutect2, varscan2
- MROH6 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1007980312, COSV99434528; called by muse, mutect2
- MTSS1 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.581); catalogued as COSV61495461; called by muse, mutect2
- NDST4 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV52113044; called by muse, mutect2, varscan2
- PPP2R3A | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 13/397 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.381); catalogued as rs1559909557; called by muse, mutect2
- PPP2R3C | c.292-1G>C p.X98_splice | Splice Site (SNP) | VAF 13/152 reads (9%) | catalogued as COSV54835193; called by muse, mutect2
- PRCC | c.1290G>C p.L430F | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV99618817; called by muse, mutect2
- TMEM132C | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs975014093; called by muse, mutect2, varscan2
- TMEM225 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.32); catalogued as COSV66693869; called by muse, mutect2, varscan2
- TMEM250 | c.126C>A p.D42E | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as COSV69307783; called by muse, mutect2, varscan2
- ZKSCAN1 | c.851C>G p.S284W | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs752416389; called by muse, mutect2, varscan2
- ZNF253 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1335917915; called by muse, mutect2
- ZSCAN29 | c.2425C>T p.H809Y | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1480469246; called by muse, mutect2
- ADGRB1 | c.2432T>C p.V811A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP29 | c.3163G>A p.G1055R | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ARHGAP5 | c.2797C>G p.L933V | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ATRIP | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- C2CD3 | c.6361G>A p.E2121K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.331); called by muse, mutect2
- CAST | c.106G>C p.E36Q (on ENST00000341926; = p.E119Q on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CCDC168 | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CDC42EP3 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 96/254 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CIITA | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- COL25A1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- COQ3 | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- DCAF1 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- EME1 | c.1688A>T p.H563L | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ERC2 | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EZH1 | c.853G>T p.V285L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FMNL1 | c.2734C>G p.L912V | Missense Mutation (SNP) | VAF 139/485 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- INHBC | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LRRC6 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LY6L | c.218A>C p.K73T | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MACROD2 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MAN2B1 | c.1956A>C p.E652D | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.029); called by muse, mutect2
- MCL1 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, varscan2
- MDN1 | c.15592G>T p.E5198* | Nonsense Mutation (SNP) | VAF 51/130 reads (39%) | called by muse, mutect2, varscan2
- MORC1 | c.1788A>T p.K596N | Missense Mutation (SNP) | VAF 177/329 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MRGPRX4 | c.564T>A p.C188* | Nonsense Mutation (SNP) | VAF 43/140 reads (31%) | called by mutect2, varscan2
- MYO1E | c.2034C>G p.I678M | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- N4BP2 | c.5107G>C p.E1703Q | Missense Mutation (SNP) | VAF 6/186 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2
- NINJ1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NKAIN2 | c.10T>A p.C4S | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- NLGN1 | c.2003A>T p.D668V | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- NMNAT2 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NPAP1 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.309); called by muse, mutect2
- NTAN1 | c.754-1G>C p.X252_splice | Splice Site (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PER3 | c.2889G>C p.E963D | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PIK3C2A | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PIK3R2 | c.381_395del p.L128_V132del | In Frame Del (DEL) | VAF 48/182 reads (26%) | called by mutect2, pindel, varscan2
- PLEKHA5 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- PNPLA5 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR1B | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- PYGL | c.2379+5G>A | Splice Region (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- SEPSECS | c.357T>A p.N119K | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SKOR2 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SNAPC2 | c.746G>T p.C249F | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SNX27 | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- SORBS2 | c.2022C>G p.H674Q | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPINT2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SRRM2 | c.4473G>C p.Q1491H | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SYNE2 | c.10344G>C p.E3448D | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TK1 | c.335T>C p.M112T | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TLN2 | c.7397G>C p.R2466T | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- TMEM131 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- TNRC6C | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- TPCN2 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- TRAPPC10 | c.613A>C p.M205L | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TREML2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TUBGCP5 | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE4B | c.3563C>G p.S1188* (on ENST00000343090 / NM_001105562.3; = p.S1059* on NM_006048.5) | Nonsense Mutation (SNP) | VAF 60/194 reads (31%) | called by muse, mutect2, varscan2
- XPO6 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- ZNF474 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF570 | c.666C>A p.D222E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AC073610.2 | c.393C>T p.H131= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- ADARB2 | c.1044G>A p.A348= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV67234600; called by muse, mutect2
- ADAT3 | c.99G>T p.G33= | Silent (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- AMDHD1 | c.1146G>C p.S382= | Silent (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.2829C>T p.T943= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs748386653; called by muse, mutect2, varscan2
- ATN1 | c.3322C>T p.L1108= | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as COSV57547471; called by muse, mutect2, varscan2
- ATRIP | c.1026C>T p.G342= | Silent (SNP) | VAF 42/68 reads (62%) | called by muse, mutect2, varscan2
- CMSS1 | c.444G>A p.K148= | Silent (SNP) | VAF 58/214 reads (27%) | called by muse, mutect2, varscan2
- COG7 | c.1273C>T p.L425= | Silent (SNP) | VAF 105/160 reads (66%) | called by muse, mutect2, varscan2
- DHX36 | c.2760G>A p.Q920= | Silent (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2, varscan2
- DNAH5 | c.10756T>C p.L3586= | Silent (SNP) | VAF 23/233 reads (10%) | called by muse, mutect2
- DSCAML1 | c.2892C>T p.N964= (on ENST00000321322; = p.N904= on NM_020693.4) | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as COSV58402945; called by muse, mutect2, varscan2
- DYTN | c.1050A>G p.R350= | Silent (SNP) | VAF 9/190 reads (5%) | called by muse, mutect2
- FBXL5 | c.30C>G p.V10= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs200927708; called by muse, mutect2, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 62/86 reads (72%) | catalogued as rs1233195687; called by muse, varscan2
- KRT78 | c.228C>A p.S76= | Silent (SNP) | VAF 82/208 reads (39%) | called by muse, mutect2, varscan2
- MCL1 | c.528G>C p.R176= | Silent (SNP) | VAF 76/218 reads (35%) | called by muse, varscan2
- NOC3L | c.78C>T p.N26= | Silent (SNP) | VAF 48/164 reads (29%) | called by muse, mutect2, varscan2
- NTN1 | c.639C>G p.L213= | Silent (SNP) | VAF 46/79 reads (58%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.2175C>T p.F725= | Silent (SNP) | VAF 13/222 reads (6%) | called by muse, mutect2
- PMM1 | c.234C>T p.A78= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs376284083; called by muse, mutect2, varscan2
- PRSS36 | c.1434C>G p.R478= | Silent (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- QRICH2 | c.747C>T p.L249= | Silent (SNP) | VAF 77/196 reads (39%) | called by muse, mutect2, varscan2
- SLC9A5 | c.1371G>A p.K457= | Silent (SNP) | VAF 65/116 reads (56%) | called by muse, mutect2, varscan2
- THAP5 | c.300C>T p.S100= (on ENST00000415914 / NM_001130475.3; = p.S58= on NM_182529.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 99/308 reads (32%) | catalogued as rs776756092; called by mutect2, varscan2
- ZIC2 | c.90G>C p.A30= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs1375995442; called by muse, mutect2, varscan2
- ZNF223 | c.927C>T p.V309= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs142054569; called by muse, mutect2, varscan2
- ZNF707 | c.828C>T p.L276= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as COSV62311268; called by muse, mutect2, varscan2
- ZNFX1 | c.3138C>T p.A1046= | Silent (SNP) | VAF 61/224 reads (27%) | called by muse, mutect2, varscan2
- ZWINT | c.657G>T p.L219= | Silent (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- AARD | c.*697T>C | 3'UTR (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- AC092687.1 | n.125G>A | RNA (SNP) | VAF 45/472 reads (10%) | called by muse, mutect2
- AC119673.2 | n.268C>A | RNA (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- AC136628.2 | n.936C>G | RNA (SNP) | VAF 19/53 reads (36%) | catalogued as rs1458286355; called by muse, mutect2, varscan2
- AFF2 | c.*7794A>G | 3'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- AKT1S1 | c.-7-1570C>T | Intron (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- AL133373.3 | n.840G>A | RNA (SNP) | VAF 9/224 reads (4%) | catalogued as rs754625249; called by muse, mutect2
- ANO1 | c.109-2216C>T | Intron (SNP) | VAF 80/205 reads (39%) | called by muse, mutect2
- ANO1 | c.*10C>T | 3'UTR (SNP) | VAF 13/27 reads (48%) | catalogued as rs371273815; called by muse, mutect2, varscan2
- APOLD1 | c.-44C>G | 5'UTR (SNP) | VAF 51/165 reads (31%) | called by muse, mutect2, varscan2
- ARX | c.*161C>T | 3'UTR (SNP) | VAF 17/20 reads (85%) | catalogued as COSV100984042; called by muse, mutect2, varscan2
- ASH1L | c.5828+4815G>T | Intron (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- BEND4 | c.*6268A>G | 3'UTR (SNP) | VAF 44/111 reads (40%) | called by muse, mutect2, varscan2
- BEST1 | c.1740-88C>T | Intron (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- CACNB2 | c.*884G>C | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- CAMKK2 | c.1596+482A>C | Intron (SNP) | VAF 49/176 reads (28%) | called by muse, varscan2
- CARMIL2 | c.1591+34C>T | Intron (SNP) | VAF 132/212 reads (62%) | called by muse, mutect2, varscan2
- CARS1 | c.*179A>C | 3'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- CEP57L1 | c.744+148G>C | Intron (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- CHST3 | c.*1769C>G | 3'UTR (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- CNPY4 | c.*515G>C | 3'UTR (SNP) | VAF 19/76 reads (25%) | catalogued as rs888236230; called by muse, mutect2, varscan2
- CNTNAP3B | c.1072-2059G>A | Intron (SNP) | VAF 62/230 reads (27%) | called by muse, mutect2, varscan2
- COA1 | c.-38-958A>G | Intron (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2936361 G>T | 3'Flank (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- CTNNBIP1 | chr1:9849540 C>G | 3'Flank (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CUX1 | c.607+25C>A | Intron (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- CUX1 | c.*4799G>C | 3'UTR (SNP) | VAF 52/172 reads (30%) | called by muse, mutect2, varscan2
- CXCL11 | c.*1032G>A | 3'UTR (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- DIPK2A | c.657+410G>A | Intron (SNP) | VAF 26/370 reads (7%) | called by muse, mutect2
- DNMT3A | c.*896C>T | 3'UTR (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- EGFR | c.*4002G>A | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- ENAH | c.803-79C>G | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- FAH | c.*33C>G | 3'UTR (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- FAM3A | c.-117G>A | 5'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- FAM53A | c.*455G>A | 3'UTR (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- FANCM | c.*821C>T | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- FBLN1 | c.1698-9615G>A | Intron (SNP) | VAF 29/88 reads (33%) | catalogued as COSV53046799; called by muse, mutect2, varscan2
- GGH | c.835+86C>G | Intron (SNP) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- GRIA4 | c.247+589A>G | Intron (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- HTR3B | c.-100G>A | 5'UTR (SNP) | VAF 40/108 reads (37%) | called by mutect2, varscan2
- IGSF9B | chr11:133956906 C>T | 5'Flank (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- IL10RB | c.-28G>A | 5'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as rs959114759; called by muse, mutect2, varscan2
- KCNJ4 | c.-30C>G | 5'UTR (SNP) | VAF 51/97 reads (53%) | catalogued as COSV100341554; called by muse, mutect2, varscan2
- KIF2A | chr5:62386407 A>G | 3'Flank (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- KRT15 | chr17:41520818 G>C | 5'Flank (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- KRTAP5-11 | c.*266C>A | 3'UTR (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- LGI1 | c.432-50T>C | Intron (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- LIF | chr22:30246902 ins G | 5'Flank (INS) | VAF 11/46 reads (24%) | catalogued as rs1047947521; called by mutect2, varscan2
- LIN9 | c.*1174del | 3'UTR (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- LINC01553 | n.2004C>G | RNA (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- LMAN1 | c.*2490G>C | 3'UTR (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- MCF2L | chr13:113099082 G>A | 3'Flank (SNP) | VAF 27/89 reads (30%) | catalogued as rs1026537027; called by muse, mutect2, varscan2
- MCFD2 | c.*1416G>T | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- MCTS1 | c.11+143C>G | Intron (SNP) | VAF 59/86 reads (69%) | called by muse, mutect2, varscan2
- MGAT3 | c.*2503C>G | 3'UTR (SNP) | VAF 48/140 reads (34%) | catalogued as rs939839691; called by muse, mutect2, varscan2
- MTDH | c.*813T>A | 3'UTR (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- MTX1 | c.598+12C>T | Intron (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- MYCBPAP | c.-9G>A | 5'UTR (SNP) | VAF 37/131 reads (28%) | called by muse, mutect2, varscan2
- NPTXR | c.*2047T>C | 3'UTR (SNP) | VAF 57/151 reads (38%) | called by muse, mutect2, varscan2
- NR4A1 | c.1158+122G>C | Intron (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- OGDH | c.*225T>C | 3'UTR (SNP) | VAF 44/133 reads (33%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-66827G>C | Intron (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- PLXNA4 | c.*4191G>A | 3'UTR (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- PLXNC1 | c.1439+15C>G | Intron (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- PNCK | c.-2-248C>T | Intron (SNP) | VAF 42/51 reads (82%) | called by muse, varscan2
- PRPSAP1 | c.*64G>A | 3'UTR (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- PTPRN2 | c.2344+3818G>A | Intron (SNP) | VAF 93/206 reads (45%) | catalogued as rs906630982; called by muse, mutect2, varscan2
- RAB9B | c.*1332G>A | 3'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- RABGGTB | chr1:75786183 G>A | 5'Flank (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- RBM39 | c.296+51C>T | Intron (SNP) | VAF 4/90 reads (4%) | catalogued as rs1273262223; called by muse, mutect2
- REG1B | c.183+30G>A | Intron (SNP) | VAF 4/95 reads (4%) | catalogued as rs1349829684; called by muse, mutect2
- RN7SL176P | chr12:100158921 G>A | 5'Flank (SNP) | VAF 35/102 reads (34%) | catalogued as rs759587404; called by muse, mutect2, varscan2
- RNASEH2C | c.*968G>A | 3'UTR (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- RPL35 | c.3+42C>G | Intron (SNP) | VAF 40/114 reads (35%) | called by muse, mutect2, varscan2
- SCAI | c.*463C>T | 3'UTR (SNP) | VAF 37/113 reads (33%) | catalogued as rs548609350; called by muse, mutect2, varscan2
- SCN1A | c.*1913C>G | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by mutect2, varscan2
- SDF2L1 | c.384+28G>C | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- SEC1P | n.601G>C | RNA (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- SERPINH1P1 | n.1076G>A | RNA (SNP) | VAF 108/383 reads (28%) | catalogued as rs1268105099; called by muse, mutect2, varscan2
- SFRP2 | c.*516C>A | 3'UTR (SNP) | VAF 32/78 reads (41%) | catalogued as rs1560809333; called by muse, mutect2, varscan2
- SHANK1 | c.1222+120G>A | Intron (SNP) | VAF 32/55 reads (58%) | called by muse, mutect2, varscan2
- SHROOM3 | c.*2311T>C | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- SLC25A36 | c.386-148T>C | Intron (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2
- SLC26A2 | c.*3427_*3447del | 3'UTR (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- SLC2A13 | c.*1015dup | 3'UTR (INS) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- SLC7A7 | c.*130T>G | 3'UTR (SNP) | VAF 54/170 reads (32%) | called by muse, varscan2
- SLFN13 | c.*2401G>A | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- SNX30 | c.*4485A>T | 3'UTR (SNP) | VAF 47/130 reads (36%) | catalogued as rs1299197789; called by muse, mutect2, varscan2
- SRRM4 | c.-290G>C | 5'UTR (SNP) | VAF 39/138 reads (28%) | called by muse, mutect2, varscan2
- TCEANC2 | c.*494G>A | 3'UTR (SNP) | VAF 51/152 reads (34%) | catalogued as rs1318835776; called by muse, mutect2, varscan2
- TCIM | c.-42C>A | 5'UTR (SNP) | VAF 87/147 reads (59%) | called by muse, mutect2, varscan2
- TECPR1 | c.*1493C>T | 3'UTR (SNP) | VAF 9/195 reads (5%) | catalogued as rs1036996956; called by muse, mutect2
- TIGD7 | c.-311G>A | 5'UTR (SNP) | VAF 9/196 reads (5%) | called by muse, mutect2
- TLCD3B | c.-117C>T | 5'UTR (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99662528; called by muse, mutect2
- TLCD3B | c.-119C>T | 5'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- TLNRD1 | c.-1214G>T | 5'UTR (SNP) | VAF 15/69 reads (22%) | catalogued as rs1196416252; called by muse, mutect2, varscan2
- TMEM8B | c.*95T>A | 3'UTR (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- TMEM9 | c.*375G>A | 3'UTR (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2
- TMPRSS7 | c.*25G>T | 3'UTR (SNP) | VAF 32/227 reads (14%) | called by muse, mutect2, varscan2
- TNIK | c.-329C>T | 5'UTR (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- TRIQK | c.*849C>G | 3'UTR (SNP) | VAF 35/92 reads (38%) | catalogued as COSV66649519; called by muse, mutect2, varscan2
- TSSK3 | c.-24G>A | 5'UTR (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- TTL | c.*354del | 3'UTR (DEL) | VAF 47/161 reads (29%) | called by mutect2, pindel, varscan2
- ULK2 | c.*40+759G>T | Intron (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- UPK1B | c.*930G>C | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- XKR6 | c.*1847_*1848insCTAT | 3'UTR (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- ZBTB21 | c.*3463G>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- ZNF532 | c.*1478G>A | 3'UTR (SNP) | VAF 97/290 reads (33%) | called by muse, mutect2, varscan2
- ZSCAN23 | c.*1619T>G | 3'UTR (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
